Somatic mutation profile of tumor specimen TCGA-EM-A2P0-01A (aliquot TCGA-EM-A2P0-01A-11D-A202-08) from TCGA case TCGA-EM-A2P0, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 33.2 years (12,127 days).
Specimen TCGA-EM-A2P0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4c55e43f-d545-42e0-adff-4794e0476ff6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EM-A2P0-10A (Blood Derived Normal), aliquot TCGA-EM-A2P0-10A-01D-A202-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/65099d5d-7d09-44fc-a088-7b3837dc38d6

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- MUC17 | c.908A>G p.N303S | Missense Mutation (SNP) | VAF 13/410 reads (3%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1324565780, COSV60279745; called by muse, mutect2
- ZFHX3 | c.7421T>G p.L2474R | Missense Mutation (SNP) | VAF 5/103 reads (5%) | SIFT tolerated (0.52); PolyPhen benign (0.368); catalogued as COSV51708320; called by muse, mutect2
- ABCC4 | c.2719_2721del p.S907del | In Frame Del (DEL) | VAF 38/138 reads (28%) | called by pindel, varscan2
